Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3605, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3605-01A (Primary Tumor).

Diagnosis:

Resected rectosigmoid colon show two sections with a moderately differentiated adenocarcinoma of the colorectal type, extending a maximum of 5 cm, with widespread infiltration of the perirectal fatty tissue and three local lymph node metastases. The broad tumor extends to the circumferential resection margin and also circumscribed in the area of the muscularis propria to the aboral resection margin.

Tumor-free oral resection margin. Tumor-free mesenteric resection margin.

Stage of tumor: pT3, pN1 (3/13) M1 (clinical liver metastases); G2, L1, V1, clinical R2

Source: NCI Genomic Data Commons file 9667a07a-7af9-4756-9a1f-9b3dad79d55c (TCGA-AG-3605.DB12396C-3CB1-428C-8598-9B4458B035BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).